Surgical pathology report (de-identified scan), TCGA case TCGA-RM-A68W, project TCGA-PCPG (Pheochromocytoma and Paraganglioma), tissue source site St. Joseph's Hospital AZ, specimen TCGA-RM-A68W-01A (Primary Tumor).

Diagnosis:

Left neck tumor, paraganglioma

Discussion:

The tumor cells demonstrate diffuse strong immunoreactivity for synaptophysin and chromogranin. S-100 highlights nerve fascicles and sustentacular cells. The histologic features, in conjunction with the immunohistochemical findings, are consistent with a paraganglioma.

Microscopic Description:

Microscopic examination reveals a paraganglioma. The tumor is characterized by nests and small lobules of neoplastic cells with neuroendocrine features. The tumor cells demonstrate round to oval nuclei with speckled chromatin and a moderate amount of weakly eosinophilic cytoplasm. Overall, cytologic atypia appears mild. Only a rare mitotic figure is seen. The nests of tumor are invested by hyalinized stroma. The specimen includes a large ganglion with accompanying nerve fascicles. The tumor lies adjacent to a network of vascular structures. Necrosis is not identified. The histologic features appear most consistent with a paraganglioma.

HIFAA Discrepancy		/
Dual/Synchronous Primary	Noted	

Source: NCI Genomic Data Commons file db0cba84-446b-480a-bf2b-4dc6ccd15da7 (TCGA-RM-A68W.969E6BA7-4BF7-4415-93D7-C60B47DD597A.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).